Somatic mutation profile of tumor specimen MP2PRT-PATBWZ-TMP1-A (aliquot MP2PRT-PATBWZ-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATBWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (939 days).
Specimen MP2PRT-PATBWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbcd4087-3776-472b-87d6-70888764f6a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBWZ-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f246f9a-9c77-460d-9b5b-0a4e0fa48531

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/584 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- DNAH9 | c.11443C>T p.R3815W | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763962085; called by muse, mutect2, varscan2
- IL13RA2 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs199942421; called by muse, mutect2
- MUC16 | c.43068G>A p.A14356= | Splice Region (SNP) | VAF 48/268 reads (18%) | catalogued as rs1385168957, COSV66692780; called by muse, mutect2, varscan2
- NALCN | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs569850296, COSV51915517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALM3 | c.748G>A p.E250K (on ENST00000340790; = p.E265K on NM_001145028.2) | Missense Mutation (SNP) | VAF 24/724 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1249268746; called by muse, mutect2
- PDS5A | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 32/289 reads (11%) | catalogued as COSV57828139; called by mutect2, varscan2
- TMEM200C | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 19/499 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1275620261; called by muse, mutect2
- PSD | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 183/538 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ADGRB2 | c.3393C>T p.C1131= | Silent (SNP) | VAF 56/420 reads (13%) | called by muse, mutect2, varscan2
- HPX | c.1122C>T p.I374= | Silent (SNP) | VAF 109/347 reads (31%) | catalogued as COSV56418515; called by muse, mutect2, varscan2
- STOX2 | c.66G>A p.P22= | Silent (SNP) | VAF 78/546 reads (14%) | catalogued as rs1000275186; called by muse, mutect2, varscan2
- WDR18 | c.489G>A p.A163= | Silent (SNP) | VAF 98/580 reads (17%) | catalogued as rs1328664100; called by muse, mutect2, varscan2
- ZNF532 | c.834C>T p.S278= | Silent (SNP) | VAF 139/470 reads (30%) | catalogued as rs745403750, COSV100266868; called by muse, mutect2, varscan2
